Somatic mutation profile of tumor specimen TCGA-AB-2833-03B (aliquot TCGA-AB-2833-03B-01W-0728-08) from TCGA case TCGA-AB-2833, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.5 years (28,308 days).
Specimen TCGA-AB-2833-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b06dd99-f6e0-49d1-984e-28564673c8e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2833-11B (Solid Tissue Normal), aliquot TCGA-AB-2833-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c4d9f8-5bbc-4329-a99c-890fb555f7a0

The open-access MAF lists 479 somatic variants for this specimen: 333 protein-altering or splice-affecting, 138 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 138, Nonsense Mutation 20, Frame Shift Ins 16, Splice Site 6, Frame Shift Del 4, Intron 4, RNA 3, Splice Region 3, IGR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.5567T>A p.M1856K (on ENST00000303395 / NM_001202435.3; = p.M1845K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs796053041, CM087901, COSV100321061; ClinVar: pathogenic; called by muse, mutect2
- AACS | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV99908136; called by muse, mutect2, varscan2
- ABCA3 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 16/412 reads (4%) | catalogued as CM074655, COSV100068785; called by muse, mutect2
- ABCF2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 52/670 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767028469, COSV99734427; called by muse, mutect2
- ACACB | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.29); catalogued as rs1247107221, COSV58136118; called by muse, mutect2
- ACLY | c.2889G>C p.M963I | Missense Mutation (SNP) | VAF 28/691 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100709766; called by muse, mutect2
- ACSF3 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs745439171, COSV100441438; called by muse, mutect2, varscan2
- ADCY2 | c.3212T>A p.L1071Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603263; called by muse, mutect2, varscan2
- ADCY5 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100567953, COSV59195474; called by muse, mutect2, varscan2
- AHNAK2 | c.2930G>A p.G977D | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.743); catalogued as COSV100318132; called by muse, mutect2, varscan2
- AHNAK2 | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100318135; called by muse, mutect2
- AHNAK2 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100318137; called by muse, mutect2
- ANGPTL2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV99401964; called by muse, mutect2, varscan2
- ANKS6 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as rs373249893; called by muse, mutect2, varscan2
- AOAH | c.836A>T p.Q279L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as COSV99333152; called by muse, mutect2, varscan2
- APBA2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 42/1028 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.997); catalogued as rs903813670, COSV68790221; called by muse, mutect2
- ARHGEF39 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as COSV100526278; called by muse, mutect2
- ARNT2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 20/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1326668677, COSV57585005; called by muse, mutect2
- ATP5PD | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100043166; called by muse, mutect2
- ATP8B2 | c.2570-1G>C p.X857_splice (on ENST00000672630; = p.X824_splice on NM_001367934.1 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 116/587 reads (20%) | catalogued as COSV100528098; called by muse, varscan2
- ATP8B2 | c.3584G>A p.S1195N (on ENST00000672630; = p.S1162N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as COSV100874513; called by muse, mutect2
- AURKAIP1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1395991271, COSV100408720; called by muse, varscan2
- B4GALT2 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434968671, COSV100530841; called by muse, varscan2
- BBS12 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100045003; called by muse, mutect2, varscan2
- BSN | c.9799A>G p.K3267E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV99608983; called by muse, varscan2
- BTN2A2 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100760493; called by muse, mutect2
- C1orf74 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs1338990046, COSV99162103; called by muse, mutect2
- C1orf74 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV99162105; called by muse, mutect2
- C20orf194 | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331004; called by muse, mutect2
- C2orf78 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV101280996; called by muse, mutect2
- C3orf20 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV99514223; called by muse, mutect2
- CAMK4 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV99999713; called by muse, mutect2, varscan2
- CARMIL3 | c.2568G>A p.L856= | Splice Region (SNP) | VAF 28/325 reads (9%) | catalogued as COSV100549713; called by muse, mutect2
- CASR | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV99949172; called by muse, mutect2
- CBLC | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV99542156; called by muse, mutect2, varscan2
- CCDC183 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100566039; called by muse, mutect2, varscan2
- CD22 | c.1061T>A p.M354K | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99323424; called by muse, mutect2
- CDH23 | c.8311G>A p.G2771S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs201076440, CM082530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK13 | c.4390G>T p.G1464C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99475749; called by muse, mutect2
- CDYL2 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980430837, COSV101629558; called by muse, varscan2
- CEACAM21 | c.847C>A p.P283T (on ENST00000401445 / NM_001098506.4; = p.P282T on NM_033543.6) | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.08); catalogued as rs1232057161, COSV99494629; called by muse, mutect2, varscan2
- CEMIP | c.618-1G>T p.X206_splice | Splice Site (SNP) | VAF 162/1532 reads (11%) | catalogued as COSV99586924; called by muse, mutect2, varscan2
- CENPF | c.4779A>T p.Q1593H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100871767; called by muse, mutect2, varscan2
- CEP112 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs373589628; called by muse, mutect2
- CEP164 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 46/1844 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV99633744; called by muse, mutect2
- CEP192 | c.2576G>A p.R859K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100381558; called by muse, mutect2, varscan2
- CLN3 | c.639G>T p.Q213H (on ENST00000360019 / NM_001286104.2; = p.Q237H on NM_000086.2) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as COSV100343482; called by muse, mutect2, varscan2
- CMYA5 | c.5386C>T p.H1796Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV101484167; called by muse, mutect2
- CNOT3 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99068980, COSV99652079; called by muse, mutect2
- COL4A1 | c.4431A>T p.Q1477H | Missense Mutation (SNP) | VAF 60/2390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101011306; called by muse, mutect2
- COL6A6 | c.5686G>A p.V1896M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1198774233, COSV62031861; called by muse, mutect2
- COX6B1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 28/675 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV55837964; called by muse, mutect2
- CPQ | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 30/330 reads (9%) | catalogued as COSV99613066; called by muse, mutect2
- CPXM1 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs267605867, COSV101013780; called by muse, mutect2, varscan2
- CXXC1 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 22/534 reads (4%) | catalogued as COSV99496644; called by muse, mutect2
- CXorf56 | c.143T>C p.L48S | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100233419; called by muse, mutect2
- DAB2IP | c.919G>A p.V307M (on ENST00000408936; = p.V279M on NM_032552.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs764203323, COSV99405812; called by muse, mutect2, varscan2
- DAGLA | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57199662; called by muse, mutect2
- DCST1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754775231, COSV99793403; called by muse, mutect2
- DCTN1 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 35/1220 reads (3%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.992); catalogued as COSV62620463; called by muse, mutect2
- DCTN1 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100720983; called by muse, mutect2, varscan2
- DCTN1 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 33/722 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs1485897831, COSV100720984; called by muse, mutect2
- DCTN3 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 26/489 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99426958; called by muse, mutect2
- DDIAS | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1370445466, COSV100231283; called by muse, mutect2
- DELE1 | c.1493T>C p.I498T | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99190824; called by muse, mutect2, varscan2
- DENND1C | c.1026dup p.Y343Vfs*17 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | catalogued as rs767870384; called by pindel, varscan2
- DGKD | c.167A>T p.K56I (on ENST00000264057 / NM_152879.3; = p.K12I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/717 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99896786; called by muse, mutect2, varscan2
- DGKG | c.2092C>A p.Q698K | Missense Mutation (SNP) | VAF 40/1520 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53963205; called by muse, mutect2
- DISP1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99451407; called by muse, mutect2, varscan2
- DNAJC22 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV101222571; called by muse, mutect2
- DNMT1 | c.2306A>G p.D769G | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100532664; called by muse, mutect2, varscan2
- DOP1B | c.4076T>C p.L1359P | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101215570; called by muse, mutect2
- DYNC1H1 | c.13567G>A p.A4523T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795091; called by muse, mutect2, varscan2
- EIF2AK4 | c.4430T>A p.V1477E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55470239, COSV99774933; called by muse, mutect2, varscan2
- EIF4A2 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV99961271; called by muse, mutect2
- EIF4G1 | c.3304G>A p.G1102R (on ENST00000346169 / NM_198241.3; = p.G907R on NM_004953.5) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100072021; called by muse, mutect2
- EIF5B | c.3103T>A p.L1035M | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99177404; called by muse, mutect2
- ENO2 | c.236G>C p.S79T | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50387570, COSV99145247; called by muse, mutect2, varscan2
- ENO3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 39/715 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); catalogued as rs1481038774, COSV99236660; called by muse, mutect2
- EPS8 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99843356; called by muse, mutect2
- ERBB3 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.312); catalogued as COSV57250214, COSV99917309; called by muse, mutect2
- EZH1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 21/652 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV101331401; called by muse, mutect2
- FARSA | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 47/524 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100108919; called by muse, mutect2
- FBN3 | c.7254C>A p.F2418L | Missense Mutation (SNP) | VAF 26/760 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99561295; called by muse, mutect2
- FKBP15 | c.3203C>T p.A1068V | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs1235474273, COSV99439204; called by muse, mutect2
- FKBP15 | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99439208; called by muse, mutect2
- FLG2 | c.5986A>G p.T1996A | Missense Mutation (SNP) | VAF 21/584 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV101166004; called by muse, mutect2
- FLOT2 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101204782; called by muse, mutect2, varscan2
- FLYWCH1 | c.1132C>T p.P378S (on ENST00000253928 / NM_001308068.2; = p.P377S on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs1463316763; called by muse, mutect2
- FOXG1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199502880; called by muse, mutect2
- FOXR1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100392955, COSV57652031; called by muse, mutect2
- FSD1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 43/1196 reads (4%) | catalogued as COSV99696871; called by muse, mutect2
- FUT6 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99744730; called by muse, mutect2
- GNB3 | c.487del p.D163Tfs*26 | Frame Shift Del (DEL) | VAF 39/306 reads (13%) | catalogued as COSV99300926; called by mutect2, pindel, varscan2
- GNL3 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 73/810 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99803935; called by muse, mutect2
- GOLGA1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763536816, COSV100764452; called by muse, mutect2, varscan2
- GP6 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs1568637691, COSV100117621; called by muse, mutect2
- GPC4 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV100895517; called by muse, mutect2, varscan2
- GPR101 | c.364A>T p.I122F | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99981498; called by muse, mutect2, varscan2
- GPRC6A | c.1468A>G p.K490E | Missense Mutation (SNP) | VAF 23/748 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.055); catalogued as COSV100114515; called by muse, mutect2
- GPSM1 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100696655; called by muse, mutect2, varscan2
- GRK7 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99380010; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99734962; called by muse, mutect2, varscan2
- HABP2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1395883386, COSV100667986; called by muse, mutect2
- HINT3 | c.537dup p.L180Tfs*19 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs773941060; called by pindel, varscan2
- HIVEP3 | c.2984A>G p.Q995R | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99913160; called by muse, mutect2, varscan2
- HMGB1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 18/324 reads (6%) | catalogued as COSV100360989; called by muse, mutect2
- HNRNPA1L2 | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100676512; called by muse, mutect2
- HNRNPM | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249293106, COSV100335292, COSV57691959; called by muse, mutect2
- HPS1 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 23/235 reads (10%) | catalogued as COSV100282672; called by muse, mutect2, varscan2
- HSD17B4 | c.2111C>A p.P704H (on ENST00000414835 / NM_001199291.3; = p.P679H on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99819957; called by muse, mutect2
- HTR3E | c.268T>C p.W90R (on ENST00000415389 / NM_001256613.1; = p.W105R on NM_182589.2) | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100094281; called by muse, mutect2
- HYOU1 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 44/688 reads (6%) | catalogued as COSV101345630; called by muse, mutect2
- ICE1 | c.6643G>A p.A2215T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99665088; called by muse, mutect2
- IDE | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99794128; called by muse, mutect2, varscan2
- IGSF10 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 32/196 reads (16%) | catalogued as COSV56791542, COSV99183565; called by muse, mutect2, varscan2
- IL6R | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100690901; called by muse, mutect2
- ILDR1 | c.832C>T p.Q278* (on ENST00000344209 / NM_001199799.2; = p.Q234* on NM_175924.4) | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV99878556; called by muse, mutect2, varscan2
- INPP4B | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53732025, COSV53739912; called by muse, mutect2
- IQCG | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV99502475; called by muse, mutect2
- ITGAV | c.411C>A p.A137= | Splice Region (SNP) | VAF 12/272 reads (4%) | catalogued as COSV53713135, COSV99655267; called by muse, mutect2
- JAG1 | c.2372G>A p.C791Y | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653161; called by muse, mutect2
- KALRN | c.3475T>C p.S1159P | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99565472; called by muse, mutect2
- KASH5 | c.856A>T p.M286L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV101483464; called by muse, mutect2, varscan2
- KCNA5 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363998; called by muse, mutect2
- KCNH2 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV100060423; called by muse, mutect2
- KCNH3 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99235445; called by muse, mutect2, varscan2
- KCNK18 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100572080; called by muse, mutect2
- KDR | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 30/1068 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV99818087; called by muse, mutect2
- KIAA1614 | c.2401T>A p.L801M | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV100851227; called by muse, mutect2
- KIR3DL2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 24/679 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1255017912; called by muse, mutect2
- KLHL4 | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 10/151 reads (7%) | catalogued as COSV100909905; called by muse, mutect2
- KLK4 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 36/720 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as COSV100133658; called by muse, mutect2
- KMT2B | c.5003G>A p.R1668Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99719971; called by muse, mutect2, varscan2
- KRTAP10-8 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100554404; called by muse, mutect2
- LCP2 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 20/544 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV50447162; called by muse, mutect2
- LDB1 | c.649G>A p.A217T (on ENST00000425280 / NM_001321612.2; = p.A181T on NM_003893.5) | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100756422; called by muse, mutect2, varscan2
- LETM1 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV100245510; called by muse, mutect2
- LRP1 | c.1980-1G>A p.X660_splice | Splice Site (SNP) | VAF 16/208 reads (8%) | catalogued as COSV99676403; called by muse, mutect2
- LRP1B | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs929613199, COSV67275497; called by muse, mutect2
- LYAR | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 96/2780 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100603518; called by muse, mutect2
- MANBA | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 20/688 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV99898893; called by muse, mutect2
- MAP3K14 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 11/225 reads (5%) | catalogued as COSV60922982; called by muse, mutect2
- MAP3K9 | c.1719G>T p.W573C | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101173686; called by muse, mutect2, varscan2
- MAP4 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99275724; called by muse, mutect2
- MAPKBP1 | c.2753G>A p.R918Q (on ENST00000456763 / NM_001128608.2; = p.R912Q on NM_014994.3) | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs201138035, COSV52968297; called by mutect2, varscan2
- MARK1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100857362; called by muse, mutect2
- MASP2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV68896969; called by muse, mutect2, varscan2
- MATK | c.674G>A p.R225K (on ENST00000310132 / NM_139355.3; = p.R226K on NM_002378.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1365048988; called by muse, mutect2
- MBD1 | c.1516C>T p.Q506* (on ENST00000269468 / NM_001323950.1; = p.Q450* on NM_015844.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | catalogued as COSV99496642; called by muse, mutect2
- MCOLN2 | c.1468T>A p.F490I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99394015; called by muse, mutect2
- MECOM | c.367A>G p.M123V (on ENST00000468789 / NM_001105078.4; = p.M311V on NM_004991.4) | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV99244903; called by muse, mutect2
- MEPCE | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as rs1049079414, COSV99440138; called by muse, mutect2
- MFSD14A | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99790940; called by muse, mutect2, varscan2
- MGAT4A | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 14/256 reads (5%) | catalogued as COSV99384481; called by muse, mutect2
- MKRN2 | c.275T>A p.V92E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.094); catalogued as COSV99403281; called by muse, mutect2, varscan2
- MMP24 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99863951; called by muse, varscan2
- MOV10 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100659650; called by muse, mutect2
- MRGPRD | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100483036; called by muse, mutect2
- MS4A1 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100619359; called by mutect2, varscan2
- MTMR1 | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100953122; called by muse, mutect2, varscan2
- MTMR11 | c.1537C>A p.L513M (on ENST00000439741 / NM_001145862.2; = p.L441M on NM_181873.3) | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); catalogued as COSV99641255; called by muse, mutect2
- MTMR4 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100051184; called by muse, mutect2, varscan2
- MYH11 | c.4756C>T p.Q1586* | Nonsense Mutation (SNP) | VAF 8/135 reads (6%) | catalogued as COSV100259494; called by muse, mutect2
- MYH11 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 20/602 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100259496; called by muse, mutect2
- MYO1B | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100269456; called by muse, mutect2
- MYOF | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV63704500; called by muse, mutect2
- MYOZ1 | c.402T>A p.H134Q | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs1451855589, COSV100831892; called by muse, mutect2
- NASP | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 11/150 reads (7%) | catalogued as COSV100601884; called by muse, mutect2
- NCAN | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99387659; called by muse, mutect2
- NCBP3 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV50106879; called by muse, mutect2, varscan2
- NDRG4 | c.320A>G p.Y107C (on ENST00000570248 / NM_001378344.1; = p.Y139C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99262296; called by muse, mutect2
- NOL4L | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1414089325, COSV100675646; called by muse, varscan2
- NOL4L | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as COSV100675649; called by muse, mutect2
- NOS1AP | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100723426; called by muse, mutect2
- NOTCH4 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746991666, COSV100900786, COSV66682005; called by muse, mutect2
- NPC1 | c.1325A>T p.Q442L | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99341524; called by muse, mutect2
- NRAP | c.4969T>C p.S1657P (on ENST00000359988 / NM_001322945.2; = p.S1622P on NM_006175.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878998890; called by muse, mutect2
- NUMA1 | c.4719+1G>A p.X1573_splice | Splice Site (SNP) | VAF 26/190 reads (14%) | catalogued as rs775465564, COSV100706341; called by muse, mutect2, varscan2
- OAS2 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 25/250 reads (10%) | catalogued as COSV100660093, COSV100660218; called by muse, mutect2, varscan2
- OPN3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 21/589 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100087554; called by muse, mutect2
- OR10G3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100336122; called by muse, mutect2, varscan2
- OR2B2 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57580767; called by muse, mutect2
- OR4C46 | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100060798; called by muse, mutect2
- OR51M1 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 118/1304 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100150295; called by muse, mutect2
- OR5H15 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 22/541 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100736703; called by muse, mutect2
- OR6Y1 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 71/1042 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as COSV100225426; called by muse, mutect2
- OSBPL10 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV101159610; called by muse, mutect2
- P3H1 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 58/1626 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1427417913, COSV99355362; called by muse, mutect2
- PAN2 | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV99228366; called by muse, mutect2
- PCDHB6 | c.257del p.N86Mfs*40 | Frame Shift Del (DEL) | VAF 88/259 reads (34%) | catalogued as COSV50701018; called by mutect2, pindel, varscan2
- PCYT1A | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV53057583, COSV99492292; called by muse, mutect2
- PDE5A | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV99308894; called by muse, mutect2
- PDP1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52601358, COSV99892603; called by muse, mutect2
- PDZK1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376348039, COSV61092217; called by muse, mutect2
- PFKM | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.323); catalogued as COSV100402567; called by muse, mutect2
- PGM2L1 | c.1742A>T p.E581V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99995019; called by muse, mutect2, varscan2
- PLCD4 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 149/1826 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as COSV101346917; called by muse, mutect2
- PLD5 | c.529A>T p.T177S (on ENST00000442594; = p.T115S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100141173; called by muse, mutect2
- PLEKHG6 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 77/455 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99164434; called by muse, mutect2, varscan2
- PLEKHO2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100060817; called by muse, mutect2, varscan2
- PLP1 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002819, CM1311157, COSV100393473; called by muse, mutect2
- PLXNC1 | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 45/602 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99313415; called by muse, mutect2
- PODXL2 | c.956A>T p.E319V | Missense Mutation (SNP) | VAF 16/546 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100686497; called by muse, mutect2
- POLG | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51523218; called by muse, varscan2
- POP7 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100292197; called by muse, mutect2
- PPP2R1B | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs782578400, COSV100232256, COSV59538052; called by muse, mutect2, varscan2
- PRDX4 | c.816A>G p.*272Wext*14 | Nonstop Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV101028736; called by muse, mutect2, varscan2
- PRR19 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100003966; called by muse, mutect2
- PRSS58 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1364200956, COSV101616143, COSV101616144; called by muse, mutect2
- PRX | c.2551T>C p.S851P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV99397809; called by muse, mutect2, varscan2
- PSMD1 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100433721, COSV58075921; called by muse, mutect2
- PTCD1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52866246, COSV99464120; called by muse, mutect2, varscan2
- PTPRE | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 35/524 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99618281; called by muse, mutect2
- QRICH1 | c.393A>T p.Q131H | Missense Mutation (SNP) | VAF 60/1404 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV100676874; called by muse, mutect2
- RALGAPB | c.1684A>G p.S562G | Missense Mutation (SNP) | VAF 42/578 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99485428; called by muse, mutect2
- RASGRP2 | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100818294; called by muse, mutect2, varscan2
- RIPK4 | c.1340-1G>A p.X447_splice (on ENST00000352483; = p.X399_splice on NM_020639.3) | Splice Site (SNP) | VAF 6/94 reads (6%) | catalogued as rs1185946766, COSV100205123; called by muse, mutect2
- RNF123 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.982); catalogued as COSV100570910; called by muse, varscan2
- ROBO4 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100127678; called by muse, mutect2
- RPS6KA1 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100837959; called by muse, mutect2, varscan2
- RTTN | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 20/476 reads (4%) | catalogued as rs1437116458, COSV99732967; called by muse, mutect2
- SCML4 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV100940358, COSV64638004; called by muse, mutect2
- SELENOV | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 37/1156 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as COSV100112797; called by muse, mutect2
- SETD2 | c.5621A>T p.K1874M | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100339400; called by muse, mutect2
- SH3TC2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100102001, COSV60462311; called by muse, mutect2
- SIGLEC11 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 100/858 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101357074; called by muse, varscan2
- SIPA1L2 | c.4666A>G p.K1556E | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV99478863; called by muse, mutect2
- SIX6 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1240398966; called by mutect2, varscan2
- SLC13A4 | c.366-2A>G p.X122_splice | Splice Site (SNP) | VAF 21/527 reads (4%) | catalogued as COSV100818901; called by muse, mutect2
- SLC2A6 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554803879, COSV100902750; called by muse, mutect2, varscan2
- SLC30A3 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1249017701, COSV99273739; called by muse, mutect2
- SLC7A10 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99472362; called by muse, mutect2, varscan2
- SLITRK2 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV59428913; called by muse, mutect2
- SLITRK3 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99579553; called by muse, mutect2
- SPARCL1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56804801; called by muse, mutect2
- SPG11 | c.6665C>T p.A2222V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99969033; called by muse, mutect2
- SPTBN1 | c.5317G>A p.A1773T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100442930; called by muse, mutect2, varscan2
- STAT6 | c.2423A>T p.E808V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV100272713; called by muse, mutect2
- TAAR6 | c.64T>C p.C22R | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs958391001, COSV99256794; called by muse, mutect2
- TAF1 | c.1167T>A p.H389Q (on ENST00000373790 / NM_138923.4; = p.H410Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99336281; called by muse, mutect2
- TAF8 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV100881151; called by muse, mutect2
- TBK1 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 21/463 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100538238, COSV59157345; called by muse, mutect2
- TCF7 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs777573831, COSV100390019; called by mutect2, varscan2
- TGM5 | c.1091A>G p.Q364R (on ENST00000220420 / NM_201631.4; = p.Q282R on NM_004245.4) | Missense Mutation (SNP) | VAF 67/803 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99589108; called by muse, mutect2
- THAP12 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52609315; called by muse, mutect2
- THSD7B | c.1454G>A p.C485Y | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753689; called by muse, mutect2
- TJAP1 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV99446966; called by muse, mutect2, varscan2
- TJAP1 | c.479A>T p.K160M (on ENST00000372445 / NM_001146016.1; = p.K150M on NM_080604.3) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99446970; called by muse, mutect2
- TMEM14B | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV101077458; called by muse, mutect2
- TMEM163 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.829); catalogued as COSV56106128, COSV99926609; called by muse, mutect2
- TSC22D4 | c.587dup p.E197Rfs*3 | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | catalogued as rs749248777; called by mutect2, pindel
- TSGA10 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs995382842, COSV100747643; called by muse, mutect2
- TTLL9 | c.565T>C p.W189R | Missense Mutation (SNP) | VAF 18/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100206959; called by muse, mutect2
- TUBA1B | c.1237A>T p.M413L | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV100254160; called by muse, varscan2
- TULP1 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 55/644 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100004273; called by muse, mutect2
- TXNDC2 | c.1288A>G p.K430E (on ENST00000306084 / NM_001098529.2; = p.K363E on NM_032243.6) | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.526); catalogued as COSV100046327; called by muse, mutect2
- UBTF | c.2039A>T p.D680V | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.207); catalogued as COSV100256005; called by muse, mutect2
- USP33 | c.2645A>T p.K882I | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100657156; called by muse, mutect2
- UTP20 | c.3947G>A p.S1316N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99881952; called by muse, mutect2
- VNN3 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 46/1516 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99258428; called by muse, mutect2
- VPS26B | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs764547459, COSV99845100; called by mutect2, varscan2
- VWF | c.8167G>A p.E2723K | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1476520970, COSV99779491; called by muse, mutect2
- WDR6 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV100556533; called by muse, mutect2
- WHRN | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54330569, COSV99470400; called by muse, mutect2
- WNK2 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs112922230, COSV99943343; called by mutect2, varscan2
- XRCC1 | c.1423T>C p.S475P | Missense Mutation (SNP) | VAF 28/927 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV99486550; called by muse, mutect2
- XRCC1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53449722, COSV99486551; called by muse, mutect2, varscan2
- XRCC6 | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV99610925; called by muse, mutect2
- ZAN | c.4160G>A p.G1387E | Missense Mutation (SNP) | VAF 69/473 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs768945587, COSV100769908; called by muse, mutect2, varscan2
- ZBTB16 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 133/718 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs755884048, COSV100251721; called by muse, mutect2, varscan2
- ZFHX3 | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1373055270, COSV99213499; called by muse, mutect2
- ZFHX4 | c.5677C>A p.P1893T | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99264654; called by muse, mutect2
- ZFY | c.1329T>A p.H443Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99324242; called by muse, mutect2
- ZNF24 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 46/1871 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99734243; called by muse, mutect2
- ZNF33B | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100847722; called by muse, mutect2, varscan2
- ZNF341 | c.1064G>T p.C355F (on ENST00000375200 / NM_001282935.1; = p.C348F on NM_032819.4) | Missense Mutation (SNP) | VAF 49/1212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100677915; called by muse, mutect2
- ZNF473 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772221333, COSV99568944; called by muse, mutect2
- ZNF490 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV100267423; called by muse, mutect2
- ZNF653 | c.1331A>T p.K444M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99542210; called by muse, mutect2
- ZNF808 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 61/1561 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100708056; called by muse, mutect2
- ZNF846 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as COSV101194353; called by muse, mutect2
- ZSWIM4 | c.424T>A p.S142T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99585086; called by muse, mutect2, varscan2
- ATP2A1 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- C9orf43 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- CCDC47 | c.632del p.G211Vfs*12 | Frame Shift Del (DEL) | VAF 59/553 reads (11%) | called by mutect2, pindel, varscan2
- CCRL2 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- DDB1 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 102/1898 reads (5%) | called by muse, mutect2
- ELMO2 | c.1768G>T p.G590W | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2
- FBN2 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRK5 | c.806dup p.D270* | Frame Shift Ins (INS) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- HDLBP | c.3289-4_3289-3del | Splice Region (DEL) | VAF 6/76 reads (8%) | called by mutect2, pindel
- HNRNPL | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 20/671 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); called by muse, mutect2
- HSPA12B | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- IFI35 | c.236dup p.S80Lfs*7 | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, varscan2
- IGF2R | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ITCH | c.2580dup p.K861Efs*13 (on ENST00000262650 / NM_001257137.3; = p.K820Efs*13 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- KCNJ14 | c.813dup p.I272Hfs*6 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel
- KMT2B | c.5909dup p.E1971* | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | called by mutect2, varscan2
- KMT2D | c.7750A>C p.T2584P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- LAMB2 | c.582dup p.R195Tfs*5 | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.1820dup p.A608Sfs*5 | Frame Shift Ins (INS) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- MBD5 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2
- MRPL45 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO18B | c.5636A>T p.D1879V | Missense Mutation (SNP) | VAF 21/657 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NKX2-3 | c.32dup p.S13Lfs*39 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- NTNG2 | c.675dup p.D226Rfs*141 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- OBSCN | c.10435G>T p.V3479L | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR51F2 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 91/3646 reads (2%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- PCSK5 | c.4836A>T p.Q1612H | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- PLPP2 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 21/534 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- POLR1B | c.1695G>C p.W565C | Missense Mutation (SNP) | VAF 22/826 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- PRF1 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2
- PROX2 | c.986del p.P329Qfs*6 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, varscan2
- PRPF8 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSG9 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 30/998 reads (3%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2
- PTH1R | c.1531dup p.R511Pfs*69 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- PUF60 | c.1574C>T p.T525I (on ENST00000526683 / NM_001362896.2; = p.T508I on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RASL11A | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RBM3 | c.12A>T p.E4D | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.029); called by mutect2, varscan2
- RNASE13 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 25/828 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- RYR1 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC16A12 | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.376); called by muse, mutect2
- SLC22A16 | c.1465A>G p.S489G | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAF2 | c.1266dup p.E423Rfs*4 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by pindel, varscan2
- TCEA3 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- TEP1 | c.7135G>A p.A2379T | Missense Mutation (SNP) | VAF 50/940 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2
- TLN1 | c.5440C>G p.L1814V | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TP53INP1 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 21/657 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TTLL12 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTLL8 | c.251dup p.L84Ffs*11 | Frame Shift Ins (INS) | VAF 21/179 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.49104dup p.P16369Tfs*3 (on ENST00000591111; = p.P8945Tfs*3 on NM_003319.4) | Frame Shift Ins (INS) | VAF 20/184 reads (11%) | called by mutect2, pindel
- ZDHHC9 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 54/619 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AAR2 | c.787C>T p.L263= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV100299356; called by muse, mutect2, varscan2
- ADAMTS8 | c.1452C>T p.P484= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs762968580, COSV99961192; called by muse, mutect2
- ADAMTSL2 | c.2343C>T p.T781= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- AIFM2 | c.582G>A p.E194= | Silent (SNP) | VAF 8/139 reads (6%) | catalogued as COSV100325754; called by muse, mutect2
- AKR1A1 | c.327G>A p.L109= | Silent (SNP) | VAF 12/330 reads (4%) | catalogued as COSV100698757; called by muse, mutect2
- AMOTL1 | c.1380G>A p.Q460= | Silent (SNP) | VAF 36/1011 reads (4%) | catalogued as COSV100504535; called by muse, mutect2
- ANKRD13C | c.102C>T p.L34= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV52030664; called by muse, mutect2
- ANKZF1 | c.2061C>T p.R687= | Silent (SNP) | VAF 16/498 reads (3%) | called by muse, mutect2
- ARHGAP6 | c.1287G>A p.V429= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs1181352793, COSV100273147; called by muse, mutect2
- ARMC4 | c.2322G>A p.V774= | Silent (SNP) | VAF 28/196 reads (14%) | catalogued as COSV100537069; called by muse, mutect2, varscan2
- ASCC3 | c.6267C>T p.V2089= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV100976692; called by muse, mutect2
- ATP2B3 | c.3432G>C p.T1144= | Silent (SNP) | VAF 51/1106 reads (5%) | catalogued as rs782570248, COSV54843766, COSV99685026; called by muse, mutect2
- BCAN | c.2397C>A p.P799= | Silent (SNP) | VAF 20/591 reads (3%) | catalogued as COSV100228098; called by muse, mutect2
- BIVM-ERCC5 | c.828C>T p.D276= | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as rs1352969856; called by muse, mutect2
- BUD13 | c.450A>G p.P150= | Silent (SNP) | VAF 40/572 reads (7%) | catalogued as COSV99496563; called by muse, mutect2
- C10orf120 | c.12A>G p.E4= | Silent (SNP) | VAF 13/354 reads (4%) | catalogued as COSV100271698; called by muse, mutect2
- C1orf127 | c.579A>T p.R193= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV100983496, COSV65436314; called by muse, mutect2, varscan2
- CACNG4 | c.849C>A p.P283= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV100047716; called by muse, mutect2
- CADM3 | c.972C>A p.S324= (on ENST00000368125 / NM_001127173.3; = p.S358= on NM_021189.5) | Silent (SNP) | VAF 137/2055 reads (7%) | catalogued as COSV100929920; called by muse, mutect2
- CAMTA1 | c.1578C>T p.T526= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs989899397, COSV100348092; called by muse, mutect2, varscan2
- CAMTA1 | c.2649A>G p.P883= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100351186; called by muse, mutect2
- CCDC65 | c.1254C>T p.L418= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV99872829; called by muse, mutect2
- CDC6 | c.1171C>T p.L391= | Silent (SNP) | VAF 59/600 reads (10%) | catalogued as rs774802926, COSV99266622; called by muse, mutect2
- CDK1 | c.309A>G p.S103= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100358867; called by muse, mutect2
- CDK5RAP2 | c.2436G>A p.Q812= | Silent (SNP) | VAF 46/798 reads (6%) | catalogued as COSV100575586; called by muse, mutect2
- CHAT | c.2193G>A p.K731= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV100340418; called by muse, mutect2
- CHD4 | c.5475C>T p.S1825= (on ENST00000357008 / NM_001363606.2; = p.S1836= on NM_001273.5) | Silent (SNP) | VAF 20/648 reads (3%) | called by muse, mutect2
- CILP | c.984G>A p.L328= | Silent (SNP) | VAF 13/319 reads (4%) | catalogued as COSV99973609; called by muse, mutect2
- CMTR1 | c.1266C>T p.C422= | Silent (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- CMTR1 | c.2397C>T p.L799= | Silent (SNP) | VAF 18/327 reads (6%) | catalogued as rs1287574280, COSV100982940; called by muse, mutect2
- COL27A1 | c.1369C>T p.L457= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100621091; called by muse, mutect2
- COL3A1 | c.1383A>G p.K461= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- COL7A1 | c.8232G>A p.E2744= | Silent (SNP) | VAF 28/414 reads (7%) | catalogued as COSV99866342; called by muse, mutect2
- CYP2E1 | c.525G>A p.A175= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs749371010, COSV99429097; called by muse, mutect2
- DHRS7B | c.663G>T p.L221= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV100684024; called by muse, mutect2
- DIPK2B | c.1275A>G p.P425= | Silent (SNP) | VAF 7/156 reads (4%) | catalogued as COSV101211686; called by muse, mutect2
- DMRT2 | c.864C>T p.S288= | Silent (SNP) | VAF 18/339 reads (5%) | catalogued as COSV99426154; called by muse, mutect2
- DNAJC11 | c.360G>A p.Q120= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99602367; called by muse, mutect2, varscan2
- DOK2 | c.1179T>A p.A393= | Silent (SNP) | VAF 20/532 reads (4%) | catalogued as COSV99374814; called by muse, mutect2
- DYSF | c.4785C>A p.P1595= | Silent (SNP) | VAF 28/403 reads (7%) | catalogued as COSV50455419; called by muse, mutect2
- EARS2 | c.789C>T p.A263= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101492179; called by muse, mutect2
- ENPP2 | c.1044G>C p.L348= (on ENST00000075322 / NM_001040092.3; = p.L400= on NM_006209.5) | Silent (SNP) | VAF 103/682 reads (15%) | catalogued as COSV99308723; called by muse, mutect2, varscan2
- F8 | c.1398A>G p.G466= | Silent (SNP) | VAF 21/588 reads (4%) | catalogued as COSV64276633; called by muse, mutect2
- FADD | c.192C>T p.R64= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs546083176, COSV100096698; called by muse, mutect2, varscan2
- FAM47C | c.2334T>C p.L778= | Silent (SNP) | VAF 2/10 reads (20%) | called by muse, mutect2
- FLRT2 | c.841C>T p.L281= | Silent (SNP) | VAF 56/622 reads (9%) | catalogued as COSV100420651; called by muse, mutect2
- FMOD | c.171G>A p.V57= | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as COSV100724571; called by muse, mutect2
- FOLR3 | c.157C>T p.L53= | Silent (SNP) | VAF 32/710 reads (5%) | catalogued as COSV61530375; called by muse, mutect2
- FOXP2 | c.2085C>T p.H695= | Silent (SNP) | VAF 22/474 reads (5%) | catalogued as COSV100646994; called by muse, mutect2
- FREM1 | c.6018G>A p.L2006= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV101084892; called by muse, mutect2, varscan2
- GCNT3 | c.615T>C p.A205= | Silent (SNP) | VAF 14/294 reads (5%) | catalogued as COSV101251841; called by muse, mutect2
- GFAP | c.579G>A p.L193= | Silent (SNP) | VAF 37/611 reads (6%) | catalogued as COSV99493426; called by muse, mutect2
- GGNBP2 | c.1797G>A p.E599= | Silent (SNP) | VAF 51/489 reads (10%) | called by muse, mutect2, varscan2
- GIGYF1 | c.492G>A p.R164= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs1453781404, COSV99309641; called by muse, mutect2
- GIMAP5 | c.765G>A p.K255= | Silent (SNP) | VAF 58/406 reads (14%) | catalogued as rs748274505, COSV100500263; called by muse, mutect2, varscan2
- GPR161 | c.186C>T p.S62= | Silent (SNP) | VAF 40/428 reads (9%) | catalogued as COSV99606898; called by muse, mutect2
- GRAMD1A | c.1605G>A p.K535= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs1382919567, COSV100526251; called by muse, mutect2
- GRM3 | c.1809C>T p.N603= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV100862670, COSV64472408; called by muse, mutect2
- HCFC1 | c.249A>G p.A83= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100129435; called by muse, varscan2
- HDLBP | c.2025G>A p.L675= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100191177; called by muse, mutect2
- HECTD4 | c.6168C>T p.C2056= | Silent (SNP) | VAF 37/510 reads (7%) | catalogued as COSV101107928; called by muse, mutect2
- HNF1B | c.783A>G p.R261= | Silent (SNP) | VAF 42/598 reads (7%) | called by muse, mutect2
- IFT22 | c.531C>T p.D177= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV100190103; called by muse, mutect2, varscan2
- IGFBP3 | c.669C>T p.H223= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99298387; called by muse, mutect2
- INTU | c.573G>A p.Q191= | Silent (SNP) | VAF 18/394 reads (5%) | catalogued as rs1000422839, COSV99611817; called by muse, mutect2
- JMJD1C | c.1857T>A p.P619= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV101232438; called by muse, mutect2
- KCNG1 | c.1284C>T p.G428= | Silent (SNP) | VAF 18/540 reads (3%) | called by muse, mutect2
- KCNH3 | c.1818C>G p.G606= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99235439; called by muse, mutect2, varscan2
- KLB | c.549G>A p.V183= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV57305541, COSV99962283; called by muse, mutect2, varscan2
- KMT2E | c.1086T>C p.F362= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV99996554; called by muse, mutect2
- KRT31 | c.1027C>T p.L343= | Silent (SNP) | VAF 52/621 reads (8%) | catalogued as COSV99289878; called by muse, mutect2
- LCOR | c.3678T>C p.Y1226= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV99617001; called by muse, mutect2
- LHFPL5 | c.441C>T p.V147= | Silent (SNP) | VAF 25/537 reads (5%) | catalogued as COSV100798989; called by muse, mutect2
- LMO7 | c.4083G>A p.E1361= (on ENST00000357063; = p.E1042= on NM_005358.5) | Silent (SNP) | VAF 24/609 reads (4%) | catalogued as rs1208982639, COSV100413536; called by muse, mutect2
- MAGI2 | c.378G>A p.Q126= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV100835220; called by muse, mutect2
- MED12 | c.1656C>T p.S552= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV100378757; called by muse, mutect2, varscan2
- MFN2 | c.1638T>C p.S546= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV99336866; called by muse, mutect2, varscan2
- MINK1 | c.2946C>T p.L982= | Silent (SNP) | VAF 44/557 reads (8%) | catalogued as rs370114801, COSV53419552; called by muse, mutect2
- MKRN1 | c.723G>A p.L241= | Silent (SNP) | VAF 18/333 reads (5%) | catalogued as COSV99751751; called by muse, mutect2
- MMP7 | c.27G>A p.V9= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs777252859, COSV99497103; called by muse, mutect2, varscan2
- MROH2B | c.2127C>T p.A709= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as COSV101270780; called by muse, mutect2, varscan2
- MRPL54 | c.369A>G p.K123= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100349714; called by muse, mutect2, varscan2
- MTMR1 | c.990T>C p.A330= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV100953120; called by muse, mutect2, varscan2
- MUC16 | c.20709T>C p.S6903= | Silent (SNP) | VAF 40/1399 reads (3%) | catalogued as COSV101200354; called by muse, mutect2
- MUC4 | c.14934T>C p.A4978= (on ENST00000463781 / NM_018406.7; = p.A742= on NM_004532.6) | Silent (SNP) | VAF 42/1488 reads (3%) | catalogued as COSV100205393; called by muse, mutect2
- MYH6 | c.4975C>T p.L1659= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as rs1231975561, COSV100676766; called by muse, mutect2
- NOA1 | c.951C>T p.S317= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99950592; called by muse, mutect2
- NOS2 | c.378C>T p.T126= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV100569757; called by muse, mutect2
- OBSCN | c.13830G>A p.L4610= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV99481093; called by muse, varscan2
- OSBPL3 | c.2248C>T p.L750= | Silent (SNP) | VAF 36/508 reads (7%) | catalogued as COSV100514279; called by muse, mutect2
- OTX2 | c.444T>C p.P148= (on ENST00000408990 / NM_172337.3; = p.P156= on NM_021728.4) | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV100258010; called by muse, mutect2
- PCDH19 | c.2709C>T p.S903= (on ENST00000373034 / NM_001184880.2; = p.S855= on NM_020766.3) | Silent (SNP) | VAF 24/474 reads (5%) | catalogued as rs1352926167, BM1418432, COSV99720190; called by muse, mutect2
- PCDHGA2 | c.822C>T p.Y274= | Silent (SNP) | VAF 16/229 reads (7%) | catalogued as rs1319429933, COSV99541589; called by muse, mutect2
- PDE1C | c.231T>A p.P77= | Silent (SNP) | VAF 33/728 reads (5%) | catalogued as COSV101275557; called by muse, mutect2
- PIK3AP1 | c.1794G>A p.A598= | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as COSV100226084, COSV59532303; called by muse, mutect2
- PRC1 | c.585C>T p.S195= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100727170; called by muse, mutect2, varscan2
- PRM2 | c.57G>A p.Q19= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV99617698; called by muse, mutect2
- PSKH1 | c.408G>A p.G136= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1274059528, COSV99344790; called by muse, mutect2, varscan2
- PTPRJ | c.3690T>C p.P1230= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as COSV101395415; called by muse, mutect2
- QSER1 | c.454T>C p.L152= (on ENST00000399302; = p.L281= on NM_001076786.3) | Silent (SNP) | VAF 15/352 reads (4%) | catalogued as COSV101234893; called by muse, mutect2
- RALGAPB | c.978C>A p.P326= | Silent (SNP) | VAF 26/628 reads (4%) | catalogued as COSV53444426; called by muse, mutect2
- RANBP10 | c.1590C>T p.G530= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100449365; called by muse, mutect2
- RASGEF1B | c.945C>T p.S315= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- SEC14L5 | c.33C>T p.V11= | Silent (SNP) | VAF 26/652 reads (4%) | catalogued as COSV99229130; called by muse, mutect2
- SEC23A | c.693A>G p.Q231= | Silent (SNP) | VAF 10/209 reads (5%) | catalogued as COSV100305641; called by muse, mutect2
- SECISBP2L | c.2442C>T p.A814= (on ENST00000559471 / NM_001193489.2; = p.A769= on NM_014701.4) | Silent (SNP) | VAF 39/592 reads (7%) | catalogued as COSV99960561; called by muse, mutect2
- SIGLEC11 | c.1785A>T p.A595= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV101357073; called by muse, mutect2
- SLC1A1 | c.39C>T p.R13= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99261461; called by muse, mutect2, varscan2
- SLC2A4 | c.369C>G p.G123= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV99142754; called by muse, mutect2
- SLC34A2 | c.1683C>T p.P561= | Silent (SNP) | VAF 35/367 reads (10%) | catalogued as rs751332566, COSV65941479; called by muse, mutect2
- SLC7A4 | c.765C>A p.A255= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100298770; called by muse, mutect2, varscan2
- SLC9A4 | c.1152C>A p.A384= | Silent (SNP) | VAF 17/262 reads (6%) | catalogued as COSV99763278; called by muse, mutect2
- SLX4 | c.4131G>A p.S1377= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as rs757513165, COSV99568249; called by muse, mutect2, varscan2
- SPG7 | c.1179G>A p.R393= (on ENST00000268704; = p.R400= on NM_003119.4) | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as COSV99245097; called by muse, mutect2, varscan2
- SPNS3 | c.1044C>T p.S348= | Silent (SNP) | VAF 116/1304 reads (9%) | catalogued as rs1390835503, COSV100337060; called by muse, mutect2
- SPOCD1 | c.2199C>T p.S733= | Silent (SNP) | VAF 14/374 reads (4%) | called by muse, mutect2
- SPPL3 | c.729T>G p.R243= | Silent (SNP) | VAF 24/395 reads (6%) | catalogued as COSV100793677; called by muse, mutect2
- SPTA1 | c.1185T>A p.A395= | Silent (SNP) | VAF 23/630 reads (4%) | catalogued as COSV100935469, COSV63752385; called by muse, mutect2
- TAPBP | c.426G>A p.Q142= | Silent (SNP) | VAF 12/375 reads (3%) | catalogued as rs148601579; called by muse, mutect2
- TARS2 | c.1491G>A p.R497= | Silent (SNP) | VAF 78/951 reads (8%) | catalogued as COSV100946027; called by muse, mutect2
- TAS2R41 | c.174G>A p.L58= | Silent (SNP) | VAF 16/355 reads (5%) | catalogued as COSV68765035; called by muse, mutect2
- TRANK1 | c.3756G>A p.E1252= | Silent (SNP) | VAF 14/370 reads (4%) | catalogued as COSV100083591; called by muse, mutect2
- TRPV3 | c.1713C>A p.S571= | Silent (SNP) | VAF 34/816 reads (4%) | catalogued as COSV100027897; called by muse, mutect2
- TRPV4 | c.1005C>A p.T335= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV99924829; called by muse, mutect2
- TRPV5 | c.204C>T p.C68= | Silent (SNP) | VAF 31/338 reads (9%) | catalogued as COSV99520703; called by muse, mutect2
- UBE2C | c.498G>A p.L166= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV99708687; called by muse, mutect2, varscan2
- ULK4 | c.459C>T p.F153= | Silent (SNP) | VAF 19/198 reads (10%) | catalogued as COSV100093530; called by muse, mutect2, varscan2
- UNC13C | c.6466C>T p.L2156= | Silent (SNP) | VAF 12/255 reads (5%) | catalogued as COSV52850232, COSV99519744; called by muse, mutect2
- UNC5B | c.1785A>G p.E595= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV100100935; called by muse, mutect2, varscan2
- VIPAS39 | c.327G>A p.L109= | Silent (SNP) | VAF 22/686 reads (3%) | catalogued as COSV100493152; called by muse, mutect2
- WDR13 | c.1368G>A p.V456= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as COSV99489470; called by muse, mutect2
- XPR1 | c.978G>A p.L326= | Silent (SNP) | VAF 20/568 reads (4%) | catalogued as COSV100851490; called by muse, mutect2
- ZKSCAN1 | c.363C>A p.P121= | Silent (SNP) | VAF 64/526 reads (12%) | catalogued as COSV100164289; called by muse, mutect2, varscan2
- ZNF229 | c.567A>G p.A189= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99350582; called by muse, mutect2
- ZNF335 | c.2586C>T p.G862= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100533171; called by muse, mutect2, varscan2
- ZNF462 | c.939C>T p.P313= | Silent (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- ZRANB2 | c.6G>A p.S2= | Silent (SNP) | VAF 18/674 reads (3%) | catalogued as COSV54671445; called by muse, mutect2
- ZSCAN10 | c.1023C>T p.R341= (on ENST00000252463; = p.R396= on NM_032805.3) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99374152; called by muse, mutect2, varscan2
- ACE | c.1922-335A>G | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99327336; called by muse, mutect2
- CCNQP1 | n.122C>A | RNA (SNP) | VAF 42/1060 reads (4%) | called by muse, mutect2
- ITGB2 | c.148-1038G>A | Intron (SNP) | VAF 10/13 reads (77%) | catalogued as rs762004170, COSV100185963; called by muse, varscan2
- MYB | c.1203+1035C>T | Intron (SNP) | VAF 24/609 reads (4%) | catalogued as COSV100214979; called by muse, mutect2
- NXF5 | n.1100G>A | RNA (SNP) | VAF 35/588 reads (6%) | called by muse, mutect2
- SLC25A3 | c.282+223G>A | Intron (SNP) | VAF 12/123 reads (10%) | catalogued as COSV99499348; called by muse, mutect2, varscan2
- SNORD115-8 | n.39A>G | RNA (SNP) | VAF 6/73 reads (8%) | catalogued as rs748243164; called by mutect2, varscan2
- Unknown | chr21:16071310 C>A | IGR (SNP) | VAF 29/696 reads (4%) | called by muse, mutect2
